Somatic mutation profile of tumor specimen TCGA-LK-A4O5-01A (aliquot TCGA-LK-A4O5-01A-11D-A34C-32) from TCGA case TCGA-LK-A4O5, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 68.4 years (25,000 days).
Specimen TCGA-LK-A4O5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5bf9218-15d7-4e87-b6e4-0110aead24b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LK-A4O5-10A (Blood Derived Normal), aliquot TCGA-LK-A4O5-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6159ead8-1edc-445b-ba2e-dec4e8aa1a2d

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Frame Shift Del 2, Nonsense Mutation 1, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.3650G>A p.G1217D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569505758, CM129372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4439A>G p.D1480G | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs886041286; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF2 | c.1346_1347del p.K449Rfs*45 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs1556001351; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CD163L1 | c.3646C>T p.H1216Y | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV100549798, COSV58014547; called by muse, mutect2, varscan2
- DLG4 | c.398C>T p.A133V (on ENST00000399506 / NM_001321075.3; = p.A176V on NM_001365.4) | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs982251458; called by muse, mutect2, varscan2
- FAM193A | c.2710C>T p.R904W | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs763351628, COSV61193445; called by muse, mutect2, varscan2
- FAT4 | c.2914G>A p.G972S | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200459486, COSV67889788; called by muse, mutect2, varscan2
- KRT4 | c.1555A>G p.R519G | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs747308373; called by muse, mutect2, varscan2
- NF2 | c.115-1G>A p.X39_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as CS002891, COSV58521769, COSV58526337, COSV58528057; called by muse, mutect2, varscan2
- OR4C15 | c.485G>T p.G162V (on ENST00000314644; = p.G108V on NM_001001920.2) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs767335394, COSV58953902; called by muse, mutect2, varscan2
- PCDHA12 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV100248744, COSV56475266; called by muse, mutect2, varscan2
- RBP3 | c.3221C>T p.T1074M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1245980865; called by muse, mutect2, varscan2
- CD6 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CERCAM | c.1159G>C p.G387R | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CLDN8 | c.114C>A p.N38K | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DDX1 | c.2119A>G p.I707V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HCN3 | c.2161C>G p.Q721E | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH1 | c.1404C>G p.N468K (on ENST00000271751 / NM_172362.3; = p.N441K on NM_002238.4) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- KIAA1549 | c.758A>T p.Y253F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- MAK16 | c.653G>T p.R218I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MBTPS2 | c.400T>A p.S134T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR1H2 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRP1 | c.1107G>T p.W369C | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN12 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RORC | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- SFMBT2 | c.385_391del p.H129Wfs*11 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- STAT2 | c.1088T>G p.I363S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- TERT | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- UBE2O | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZGPAT | c.380A>C p.E127A | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CADPS2 | c.1971C>T p.H657= | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- COL12A1 | c.6747A>G p.T2249= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs1254008821, COSV59408088; called by muse, mutect2, varscan2
- COL13A1 | c.1131C>T p.G377= (on ENST00000398978 / NM_001130103.2; = p.G320= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs1475875241; called by muse, mutect2, varscan2
- DDX41 | c.522C>T p.D174= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs924815407, COSV57902786; called by muse, mutect2, varscan2
- FAHD1 | c.516C>T p.I172= | Silent (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- ISG20L2 | c.402C>T p.T134= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100494015; called by muse, mutect2, varscan2
- MAP1A | c.5475C>T p.L1825= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs372304600; called by muse, mutect2, varscan2
- PLEKHG3 | c.2343C>T p.A781= (on ENST00000394691; = p.A837= on NM_001308147.2) | Silent (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- SERPINB3 | c.96C>T p.I32= | Silent (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- TBATA | c.621C>T p.G207= | Silent (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5731C>T | Intron (SNP) | VAF 40/108 reads (37%) | catalogued as rs144758799; called by muse, mutect2, varscan2
- SSPOP | n.14947G>A | RNA (SNP) | VAF 15/50 reads (30%) | catalogued as rs368194421; called by muse, mutect2, varscan2
